Somatic mutation profile of tumor specimen ASCProject_0261_T1_WES (aliquot ASCProject_0261_T1_WES_1) from CMI case ASCProject_0261, project CMI-ASC: Count Me In (CMI): The Angiosarcoma (ASC) Project. Sex at birth: male; Primary diagnosis: Angiosarcoma; Tissue or organ of origin: Spleen; Age at diagnosis: 62.9 years (22,962 days).
Specimen ASCProject_0261_T1_WES: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Spleen; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) d7fdc6ce-31ac-41c8-a53a-9acfdadd296c.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen ASCProject_0261_SALIVA (Saliva), aliquot ASCProject_0261_SALIVA_1; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/2330f18b-f9ea-4389-8f54-834503a4845e

The open-access MAF lists 72 somatic variants for this specimen: 52 protein-altering or splice-affecting, 14 silent, 6 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 44, Silent 14, Translation Start Site 2, 5'UTR 2, Nonsense Mutation 2, Frame Shift Del 2, Splice Site 2, Intron 2, RNA 1, 5'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.919+1G>T p.X307_splice | Splice Site (SNP) | VAF 133/860 reads (15%) | hotspot (GDC flag); catalogued as rs1131691039, CD920913, CS107068, CS120864, COSV52683145, COSV52775982, COSV52814989; ClinVar: not provided / likely pathogenic; called by muse, mutect2, varscan2
- DKKL1 | c.574G>A p.E192K | Missense Mutation (SNP) | VAF 46/406 reads (11%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.766); catalogued as rs998748923, COSV99678559; called by muse, mutect2, varscan2
- DNAH5 | c.2791G>C p.A931P | Missense Mutation (SNP) | VAF 14/285 reads (5%) | SIFT tolerated (0.31); PolyPhen benign (0.106); catalogued as COSV99453063; called by muse, mutect2
- DQX1 | c.953G>A p.R318Q | Missense Mutation (SNP) | VAF 105/804 reads (13%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.991); catalogued as rs749983331, COSV66353228; called by muse, mutect2, varscan2
- DSC1 | c.1987A>T p.R663* | Nonsense Mutation (SNP) | VAF 15/221 reads (7%) | catalogued as COSV57149863; called by muse, mutect2
- DSCAM | c.5455G>A p.E1819K | Missense Mutation (SNP) | VAF 37/219 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as COSV68030907; called by muse, mutect2, varscan2
- GK2 | c.1486A>C p.S496R | Missense Mutation (SNP) | VAF 27/231 reads (12%) | SIFT tolerated (1); PolyPhen benign (0.015); catalogued as COSV62626297; called by muse, mutect2, varscan2
- IZUMO3 | c.593G>T p.C198F (on ENST00000543880 / NM_001365008.2; = p.C192F on NM_001271706.1) | Missense Mutation (SNP) | VAF 9/102 reads (9%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.516); catalogued as rs913562068; called by muse, mutect2
- MAP4K1 | c.29A>G p.N10S | Missense Mutation (SNP) | VAF 108/558 reads (19%) | SIFT tolerated (0.08); PolyPhen benign (0.057); catalogued as rs751124465; called by muse, mutect2, varscan2
- MOS | c.151G>A p.A51T | Missense Mutation (SNP) | VAF 69/394 reads (18%) | SIFT deleterious (0.03); PolyPhen benign (0.401); catalogued as rs758487537; called by muse, mutect2, varscan2
- OR2T33 | c.748T>G p.Y250D | Missense Mutation (SNP) | VAF 26/422 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV58814468, COSV58816395; called by muse, mutect2
- PID1 | c.545G>A p.W182* (on ENST00000354069 / NM_001330156.1; = p.W180* on NM_017933.5) | Nonsense Mutation (SNP) | VAF 107/864 reads (12%) | catalogued as COSV62477940, COSV62484632; called by muse, mutect2, varscan2
- RUNX1T1 | c.824G>A p.R275Q (on ENST00000265814 / NM_001198628.1; = p.R248Q on NM_004349.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 56/771 reads (7%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.922); catalogued as rs748284068, COSV56140843, COSV56146054; called by muse, mutect2
- SEMG1 | c.156A>C p.K52N | Missense Mutation (SNP) | VAF 10/120 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.961); catalogued as COSV99725060; called by muse, mutect2
- SFMBT2 | c.11C>A p.T4N | Missense Mutation (SNP) | VAF 12/128 reads (9%) | SIFT tolerated, low confidence (0.29); PolyPhen benign (0); catalogued as COSV100738242; called by muse, mutect2
- SLITRK4 | c.340T>G p.L114V | Missense Mutation (SNP) | VAF 13/89 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.925); catalogued as COSV100567117, COSV62026951; called by muse, mutect2, varscan2
- TERT | c.2086C>T p.R696C | Missense Mutation (SNP) | VAF 15/248 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.939); catalogued as rs973201915, COSV57206668; called by muse, mutect2
- TFAP2C | c.917T>C p.V306A | Missense Mutation (SNP) | VAF 75/464 reads (16%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.997); catalogued as COSV52373312; called by muse, mutect2, varscan2
- ADAMTS13 | c.2532G>T p.E844D | Missense Mutation (SNP) | VAF 40/347 reads (12%) | SIFT tolerated (0.61); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- ADGRG3 | c.536A>G p.N179S | Missense Mutation (SNP) | VAF 105/606 reads (17%) | SIFT tolerated (0.06); PolyPhen benign (0.433); called by muse, mutect2, varscan2
- ASPH | c.1375G>T p.D459Y | Missense Mutation (SNP) | VAF 24/123 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); called by muse, mutect2, varscan2
- CACNA1I | c.1198C>A p.Q400K | Missense Mutation (SNP) | VAF 11/132 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.931); called by muse, mutect2
- CFAP58 | c.1168A>C p.N390H | Missense Mutation (SNP) | VAF 8/128 reads (6%) | SIFT tolerated (0.16); PolyPhen benign (0.021); called by muse, mutect2
- CHGA | c.920A>G p.E307G | Missense Mutation (SNP) | VAF 37/461 reads (8%) | SIFT tolerated (0.07); PolyPhen benign (0.19); called by muse, mutect2
- DNAH6 | c.953A>T p.K318I | Missense Mutation (SNP) | VAF 14/125 reads (11%) | SIFT deleterious (0.05); PolyPhen benign (0.052); called by muse, mutect2
- GCFC2 | c.581G>T p.R194I | Missense Mutation (SNP) | VAF 34/348 reads (10%) | SIFT deleterious (0); PolyPhen benign (0.015); called by muse, mutect2
- GLRB | c.989A>C p.D330A | Missense Mutation (SNP) | VAF 36/451 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2
- IMPA2 | c.486G>T p.E162D | Missense Mutation (SNP) | VAF 9/184 reads (5%) | SIFT deleterious (0.01); PolyPhen benign (0.299); called by muse, mutect2
- INMT | c.323C>A p.T108N | Missense Mutation (SNP) | VAF 18/348 reads (5%) | SIFT deleterious (0); PolyPhen benign (0.169); called by muse, mutect2
- IZUMO1R | c.449G>C p.W150S (on ENST00000440961; = p.W157S on NM_001199206.3) | Missense Mutation (SNP) | VAF 38/309 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.98); called by muse, mutect2, varscan2
- MC5R | c.505T>G p.F169V | Missense Mutation (SNP) | VAF 79/580 reads (14%) | SIFT tolerated (0.44); PolyPhen possibly damaging (0.676); called by muse, mutect2, varscan2
- MDFIC | c.611G>A p.C204Y | Missense Mutation (SNP) | VAF 62/688 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- MEI1 | c.3481del p.D1161Mfs*13 | Frame Shift Del (DEL) | VAF 35/355 reads (10%) | called by mutect2, pindel, varscan2
- MUC22 | c.1841A>C p.E614A | Missense Mutation (SNP) | VAF 30/322 reads (9%) | SIFT tolerated (0.08); called by muse, mutect2
- MYO1A | c.1164+1G>C p.X388_splice | Splice Site (SNP) | VAF 46/536 reads (9%) | called by muse, mutect2
- NCDN | c.2T>C p.M1? | Translation Start Site (SNP) | VAF 20/378 reads (5%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.042); called by muse, mutect2
- NEB | c.1061A>C p.K354T | Missense Mutation (SNP) | VAF 19/240 reads (8%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.995); called by muse, mutect2
- NR3C1 | c.280_281del p.E94Nfs*7 | Frame Shift Del (DEL) | VAF 89/618 reads (14%) | called by mutect2, pindel, varscan2
- PDPR | c.58C>A p.Q20K | Missense Mutation (SNP) | VAF 42/580 reads (7%) | SIFT tolerated, low confidence (0.41); PolyPhen benign (0.001); called by muse, mutect2
- RPL27A | c.2T>G p.M1? | Translation Start Site (SNP) | VAF 25/292 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.762); called by muse, mutect2
- SCN10A | c.4596G>T p.Q1532H | Missense Mutation (SNP) | VAF 34/174 reads (20%) | SIFT tolerated (1); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- SDK1 | c.3239A>C p.N1080T | Missense Mutation (SNP) | VAF 30/408 reads (7%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.481); called by muse, mutect2
- SLITRK6 | c.2426G>A p.R809K | Missense Mutation (SNP) | VAF 28/176 reads (16%) | SIFT tolerated (0.79); PolyPhen benign (0.444); called by muse, mutect2, varscan2
- SPATA18 | c.934C>G p.Q312E | Missense Mutation (SNP) | VAF 28/536 reads (5%) | SIFT tolerated (0.34); PolyPhen possibly damaging (0.641); called by muse, mutect2
- SULT4A1 | c.29G>T p.S10I | Missense Mutation (SNP) | VAF 21/241 reads (9%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.969); called by muse, mutect2
- TM6SF1 | c.884C>T p.P295L | Missense Mutation (SNP) | VAF 30/300 reads (10%) | SIFT tolerated (0.99); PolyPhen benign (0.419); called by muse, varscan2
- TMEM269 | c.80A>G p.N27S | Missense Mutation (SNP) | VAF 39/276 reads (14%) | SIFT tolerated (0.78); PolyPhen benign (0.013); called by muse, mutect2, varscan2
- TRERF1 | c.474G>T p.Q158H | Missense Mutation (SNP) | VAF 56/620 reads (9%) | SIFT tolerated, low confidence (0.06); PolyPhen probably damaging (0.983); called by muse, mutect2
- TRIM71 | c.2083A>G p.T695A | Missense Mutation (SNP) | VAF 23/164 reads (14%) | SIFT tolerated (0.19); PolyPhen benign (0.017); called by muse, mutect2, varscan2
- UGT1A6 | c.40G>A p.G14R | Missense Mutation (SNP) | VAF 23/457 reads (5%) | SIFT tolerated (0.37); PolyPhen benign (0.282); called by muse, mutect2
- VCX | c.257A>G p.Q86R | Missense Mutation (SNP) | VAF 22/386 reads (6%) | SIFT tolerated (0.1); PolyPhen benign (0.003); called by muse, mutect2
- ZNF597 | c.944A>T p.E315V | Missense Mutation (SNP) | VAF 13/189 reads (7%) | SIFT deleterious (0.02); PolyPhen benign (0.116); called by muse, mutect2
- ADGRA1 | c.654G>A p.Q218= | Silent (SNP) | VAF 15/125 reads (12%) | called by muse, mutect2, varscan2
- COL4A3 | c.3765C>A p.P1255= | Silent (SNP) | VAF 28/281 reads (10%) | called by muse, mutect2, varscan2
- CUL7 | c.786G>A p.S262= | Silent (SNP) | VAF 28/199 reads (14%) | catalogued as rs1373198486, COSV54815577, COSV54820075; called by muse, mutect2, varscan2
- EYA1 | c.237T>C p.T79= | Silent (SNP) | VAF 101/554 reads (18%) | catalogued as rs1172949131; called by muse, mutect2, varscan2
- GPATCH1 | c.1362C>T p.D454= | Silent (SNP) | VAF 19/278 reads (7%) | called by muse, mutect2
- KRT78 | c.1488C>T p.S496= | Silent (SNP) | VAF 40/576 reads (7%) | called by muse, mutect2
- MYO1H | c.924C>T p.A308= | Silent (SNP) | VAF 19/127 reads (15%) | called by muse, mutect2, varscan2
- OR1G1 | c.606T>A p.T202= | Silent (SNP) | VAF 24/476 reads (5%) | called by muse, mutect2
- OR6Y1 | c.363T>A p.A121= | Silent (SNP) | VAF 32/390 reads (8%) | catalogued as COSV56928105; called by muse, mutect2
- OTOG | c.4335C>T p.C1445= | Silent (SNP) | VAF 47/325 reads (14%) | called by muse, mutect2, varscan2
- PSG1 | c.699G>T p.L233= | Silent (SNP) | VAF 16/199 reads (8%) | called by muse, mutect2
- SLC38A5 | c.372G>A p.K124= | Silent (SNP) | VAF 17/271 reads (6%) | called by muse, mutect2
- SLC39A5 | c.609T>A p.P203= | Silent (SNP) | VAF 30/403 reads (7%) | catalogued as COSV57191729; called by muse, mutect2
- SMURF2 | c.2109T>C p.I703= | Silent (SNP) | VAF 26/530 reads (5%) | catalogued as COSV52318185; called by muse, mutect2
- FMO9P | n.224C>A | RNA (SNP) | VAF 20/180 reads (11%) | catalogued as rs1348902989; called by mutect2, varscan2
- SERPINA9 | chr14:94476220 A>C | 5'Flank (SNP) | VAF 32/396 reads (8%) | catalogued as rs537664780, COSV54078951; called by muse, mutect2
- SLC13A3 | c.1122-2018A>C | Intron (SNP) | VAF 9/94 reads (10%) | called by muse, mutect2
- SLC1A3 | c.-35A>C | 5'UTR (SNP) | VAF 12/169 reads (7%) | catalogued as COSV54314725; called by muse, mutect2
- VWA3A | c.2840-591G>T | Intron (SNP) | VAF 10/188 reads (5%) | called by muse, mutect2
- XRCC5 | c.-55G>A | 5'UTR (SNP) | VAF 66/784 reads (8%) | called by muse, mutect2
